Somatic mutation profile of tumor specimen MMRF_2621_1_PB_CD138pos (aliquot MMRF_2621_1_PB_CD138pos_T3_KHS5U_L12898) from MMRF case MMRF_2621, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.2 years (19,071 days).
Specimen MMRF_2621_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 979381ed-9069-49a1-a9f8-60d6b5ed1e54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2621_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2621_1_PB_CD3pos_C5_KHS5U_L12899; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87cbe3b1-3e76-4924-a37e-e1395b7a3f19

The open-access MAF lists 14 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 5, Missense Mutation 5, Silent 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH8 | c.4489C>A p.L1497I | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59422153; called by muse, mutect2
- GADD45B | c.146+7C>T | Splice Region (SNP) | VAF 16/38 reads (42%) | catalogued as COSV99298039; called by muse, mutect2, varscan2
- HSCB | c.382T>G p.Y128D | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750556206; called by muse, mutect2, varscan2
- SLC6A3 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1431359180; called by muse, mutect2, varscan2
- ZNF205 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs752402312; called by muse, mutect2, varscan2
- PTX3 | c.167G>T p.W56L | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACTG1 | c.234C>T p.N78= | Silent (SNP) | VAF 52/138 reads (38%) | catalogued as rs553335992; called by muse, mutect2, varscan2
- DNAH8 | c.4491T>G p.L1497= | Silent (SNP) | VAF 42/118 reads (36%) | called by muse, mutect2
- PRMT6 | c.1110C>T p.D370= | Silent (SNP) | VAF 10/137 reads (7%) | catalogued as rs1169939697; called by muse, mutect2
- BPNT2 | c.*5089G>A | 3'UTR (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- DGKI | c.*138A>T | 3'UTR (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- KLF6 | c.*2562A>G | 3'UTR (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- SPSB1 | c.*1274A>T | 3'UTR (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- WDR37 | c.*1210C>T | 3'UTR (SNP) | VAF 21/109 reads (19%) | catalogued as rs149197659; called by muse, mutect2, varscan2
